Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A28E, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A28E-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	Sigmoid Distal
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Moderately Differentiated
Mucinous:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	None
Crohn's like reaction	☒ None ☐ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☒ Expansile ☐ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☒ No ☐ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	0
Pathologist Comment:	

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: sigmoid colon C18.7

W 5/3/11

Source: NCI Genomic Data Commons file 222b0546-f84f-4839-a87c-458ba85c4fac (TCGA-DM-A28E.6BA78869-CE10-4755-82A8-9096731A069C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).